Gene-level copy-number profile of tumor specimen TCGA-G3-A5SL-01A from TCGA case TCGA-G3-A5SL, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 70.3 years (25,671 days).
Specimen TCGA-G3-A5SL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.d709ff06-28c6-42ab-bc2d-d4953d0c77b9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G3-A5SL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2500827b-210d-41a7-ab58-893839965072

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,752; copy number 2: 43,267; copy number 3: 6,257; copy number 4: 1,480; copy number 5: 1,321; copy number 6: 209; copy number 7: 212; copy number 8: 1,156; copy number 9: 163; copy number 10: 2; copy number 18: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G3-A5SL-01A-11D-A27H-01): tumor purity 0.77, ploidy 2.3, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,064 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:669,081–62,461,503, 1,528 genes, copy number 5–6 (within-gene range 5–8) (broad region; genes not listed).
- chr7:126,495,312–126,531,336, 2 genes, copy number 5 (within-gene range 3–5): AC002057.2, AC000374.1.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 7–18 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,372. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
